Somatic mutation profile of tumor specimen TCGA-A2-A1G6-01A (aliquot TCGA-A2-A1G6-01A-11D-A13L-09) from TCGA case TCGA-A2-A1G6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.7 years (18,514 days).
Specimen TCGA-A2-A1G6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d476a816-2034-417f-b5bd-ecf4c7de63ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A1G6-10A (Blood Derived Normal), aliquot TCGA-A2-A1G6-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ea02a72-0485-4c07-a5a0-9e71da98ad10

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKHD1-EIF4EBP3 | c.1529C>G p.T510S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99784812; called by muse, mutect2
- APOOL | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100920973; called by muse, mutect2
- ASXL3 | c.6683C>T p.A2228V | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99327062; called by muse, mutect2
- MORC2 | c.647T>C p.I216T (on ENST00000397641 / NM_001303256.3; = p.I154T on NM_014941.3) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV53200079; called by muse, mutect2
- PM20D1 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as COSV65649201; called by muse, mutect2, varscan2
- SPG11 | c.3893-1G>T p.X1298_splice | Splice Site (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99969874; called by muse, mutect2
- SLC25A42 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
